Somatic mutation profile of cancer-model specimen HCM-BROD-0745-C43-85M (Adherent Cell Line, passage 9; aliquot HCM-BROD-0745-C43-85M-01D-A85C-36), derived from the metastatic tumor of HCMI case HCM-BROD-0745-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 69.3 years (25,306 days).
Specimen HCM-BROD-0745-C43-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 9.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 80cda212-58a4-4730-bd52-ff6a65aa8b8f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0745-C43-10A (Blood Derived Normal), aliquot HCM-BROD-0745-C43-10A-01D-A85C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fb36b6a5-b87c-4521-ba3e-2951d0950ae3

The open-access MAF lists 535 somatic variants for this specimen: 337 protein-altering or splice-affecting, 178 silent, 20 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 302, Silent 178, Nonsense Mutation 20, Intron 14, Splice Region 7, Frame Shift Ins 4, 3'Flank 3, Frame Shift Del 3, 3'UTR 2, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 156/348 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- LPA | c.109C>T p.R37* | Nonsense Mutation (SNP) | VAF 95/297 reads (32%) | catalogued as rs121912503, COSV60296281; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCB1 | c.2528T>G p.L843R | Missense Mutation (SNP) | VAF 81/395 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55944976; called by muse, mutect2, varscan2
- ADAM23 | c.1598C>T p.S533F | Missense Mutation (SNP) | VAF 187/370 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs779263287; called by muse, mutect2, varscan2
- ADAMTSL2 | c.1690G>A p.D564N | Missense Mutation (SNP) | VAF 417/1037 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs867693203; called by muse, mutect2, varscan2
- AFF2 | c.2740C>T p.P914S | Missense Mutation (SNP) | VAF 341/342 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53977388; called by muse, mutect2, varscan2
- AGO3 | c.182G>A p.R61K | Missense Mutation (SNP) | VAF 129/240 reads (54%) | SIFT tolerated (0.57); PolyPhen benign (0.012); catalogued as COSV99867878; called by muse, varscan2
- AHNAK | c.13915C>T p.P4639S | Missense Mutation (SNP) | VAF 182/468 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV57211015; called by muse, varscan2
- ALK | c.896C>T p.S299F | Missense Mutation (SNP) | VAF 280/522 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); catalogued as COSV66557187; called by muse, varscan2
- AMER3 | c.1169C>T p.S390F | Missense Mutation (SNP) | VAF 300/543 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.427); catalogued as COSV58465537; called by muse, varscan2
- ARHGAP32 | c.5686C>T p.P1896S (on ENST00000310343 / NM_001378025.1; = p.P1547S on NM_014715.4) | Missense Mutation (SNP) | VAF 224/404 reads (55%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.021); catalogued as rs1170742059; called by muse, varscan2
- ASXL3 | c.5479C>T p.P1827S | Missense Mutation (SNP) | VAF 226/408 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99325841; called by muse, mutect2, varscan2
- ATE1 | c.1111G>A p.D371N | Missense Mutation (SNP) | VAF 269/269 reads (100%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as rs773450449, COSV56435136; called by muse, mutect2, varscan2
- BMP4 | c.464C>T p.S155F | Missense Mutation (SNP) | VAF 200/473 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV55415221, COSV55415481, COSV99816684; called by muse, varscan2
- CACNA1H | c.1502G>A p.G501E | Missense Mutation (SNP) | VAF 266/690 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.381); catalogued as rs768197900; ClinVar: likely benign; called by muse, varscan2
- CADPS | c.1928G>A p.G643E | Missense Mutation (SNP) | VAF 240/388 reads (62%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.554); catalogued as COSV51872873; called by muse, mutect2, varscan2
- CAMSAP2 | c.1579C>T p.H527Y (on ENST00000236925 / NM_001297707.2; = p.H516Y on NM_203459.3) | Missense Mutation (SNP) | VAF 184/280 reads (66%) | SIFT tolerated (1); PolyPhen benign (0.129); catalogued as COSV99373049; called by muse, varscan2
- CAPZA3 | c.74G>A p.G25E | Missense Mutation (SNP) | VAF 165/546 reads (30%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV99856427; called by muse, varscan2
- CCDC40 | c.3086C>T p.S1029F | Missense Mutation (SNP) | VAF 161/518 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as rs760397607; called by muse, mutect2, varscan2
- CD163 | c.2330G>A p.G777E | Missense Mutation (SNP) | VAF 193/527 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63133423; called by muse, varscan2
- CD163 | c.1736G>A p.R579K | Missense Mutation (SNP) | VAF 193/523 reads (37%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.764); catalogued as COSV63136965; called by muse, mutect2, varscan2
- CD2 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 152/335 reads (45%) | SIFT tolerated (0.84); PolyPhen benign (0.001); catalogued as rs769894316; called by muse, varscan2
- CD247 | c.290G>A p.G97E | Missense Mutation (SNP) | VAF 237/362 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100758350; called by muse, mutect2, varscan2
- CDH12 | c.1658G>A p.R553Q | Missense Mutation (SNP) | VAF 212/439 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as rs374444907; called by muse, mutect2, varscan2
- CDHR1 | c.1120G>A p.G374R | Missense Mutation (SNP) | VAF 217/217 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756969177; called by muse, varscan2
- CELSR2 | c.6919C>T p.R2307C | Missense Mutation (SNP) | VAF 325/623 reads (52%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.793); catalogued as rs1366132430, COSV54768919; called by muse, mutect2, varscan2
- CHRNB3 | c.410C>T p.S137L | Missense Mutation (SNP) | VAF 270/270 reads (100%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as rs1418024205, COSV51493359, COSV51495659; called by muse, mutect2, varscan2
- CKMT1A | c.931G>A p.G311R | Missense Mutation (SNP) | VAF 135/358 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs767898760; called by muse, mutect2, varscan2
- CLEC18B | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 201/443 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as rs1473630019; called by muse, mutect2, varscan2
- CLVS2 | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 222/342 reads (65%) | SIFT tolerated (0.3); PolyPhen benign (0.328); catalogued as COSV51565713; called by muse, mutect2, varscan2
- CNTN5 | c.2573G>A p.G858E | Missense Mutation (SNP) | VAF 120/224 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs867933506, COSV54343942; called by muse, varscan2
- COL12A1 | c.9091A>T p.N3031Y | Missense Mutation (SNP) | VAF 205/643 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100485445; called by muse, mutect2, varscan2
- COL12A1 | c.7840C>T p.P2614S | Missense Mutation (SNP) | VAF 143/230 reads (62%) | SIFT deleterious (0.05); PolyPhen benign (0.037); catalogued as rs772870762, COSV59397992; called by muse, mutect2, varscan2
- CRTC2 | c.349C>T p.P117S | Missense Mutation (SNP) | VAF 115/385 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.229); catalogued as COSV100135636; called by muse, mutect2, varscan2
- CRYBG1 | c.5465G>A p.R1822Q | Missense Mutation (SNP) | VAF 27/166 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.021); catalogued as rs767966320, COSV64810992; called by muse, mutect2, varscan2
- CYLC1 | c.1501G>A p.E501K | Missense Mutation (SNP) | VAF 280/280 reads (100%) | SIFT tolerated (1); PolyPhen benign (0.324); catalogued as COSV61413401; called by muse, mutect2, varscan2
- DEFB119 | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 144/475 reads (30%) | SIFT tolerated, low confidence (0.97); PolyPhen benign (0.003); catalogued as rs1184134834; called by muse, mutect2, varscan2
- DMBT1 | c.5383G>A p.D1795N (on ENST00000338354 / NM_001377530.1; = p.D1038N on NM_004406.3) | Missense Mutation (SNP) | VAF 420/420 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs760683143, COSV57535850, COSV57547017; called by muse, varscan2
- DNAH5 | c.6764G>A p.R2255Q | Missense Mutation (SNP) | VAF 345/736 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1317585354, COSV54235046; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH8 | c.11186C>T p.P3729L | Missense Mutation (SNP) | VAF 102/194 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.063); catalogued as rs142032754; called by muse, varscan2
- DNAH9 | c.2275C>T p.P759S | Missense Mutation (SNP) | VAF 118/118 reads (100%) | SIFT deleterious (0.03); PolyPhen benign (0.158); catalogued as COSV52359825; called by muse, varscan2
- DYNC2H1 | c.3344C>T p.S1115F | Missense Mutation (SNP) | VAF 98/252 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.076); catalogued as rs1409098412; called by muse, mutect2, varscan2
- EDN2 | c.497G>A p.R166Q | Missense Mutation (SNP) | VAF 154/587 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.036); catalogued as rs181076869; called by muse, mutect2, varscan2
- EGFR | c.970C>T p.R324C | Missense Mutation (SNP) | VAF 242/415 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1343888047; called by muse, mutect2, varscan2
- EML6 | c.2321G>T p.G774V | Missense Mutation (SNP) | VAF 188/448 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62868220; called by muse, varscan2
- EPPK1 | c.2819C>T p.S940F | Missense Mutation (SNP) | VAF 300/708 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.359); catalogued as rs1470942284; called by muse, mutect2, varscan2
- EVPL | c.4711G>A p.G1571R | Missense Mutation (SNP) | VAF 238/788 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs774963318; called by muse, varscan2
- FAM53C | c.662C>T p.S221F | Missense Mutation (SNP) | VAF 531/531 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.466); catalogued as rs1252345775; called by muse, mutect2, varscan2
- FBXL13 | c.1388G>A p.R463K | Missense Mutation (SNP) | VAF 158/308 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); catalogued as COSV100502235; called by muse, varscan2
- FDXACB1 | c.788A>C p.K263T | Missense Mutation (SNP) | VAF 204/362 reads (56%) | SIFT tolerated (0.1); PolyPhen benign (0.231); catalogued as rs1381030608; called by muse, varscan2
- FECH | c.887C>T p.P296L | Missense Mutation (SNP) | VAF 190/334 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs929058991, COSV50491038; called by muse, mutect2, varscan2
- FLG | c.3827G>A p.S1276N | Missense Mutation (SNP) | VAF 115/343 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.326); catalogued as COSV64244884; called by muse, mutect2, varscan2
- FLNB | c.7642G>A p.G2548R | Missense Mutation (SNP) | VAF 114/308 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs1411322123, COSV99914177; called by muse, varscan2
- FLT1 | c.1301C>T p.A434V | Missense Mutation (SNP) | VAF 129/277 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.2); catalogued as COSV56728367, COSV56741828; called by muse, mutect2, varscan2
- FN1 | c.6979G>A p.G2327S (on ENST00000359671 / NM_001365524.2; = p.G2296S on NM_002026.4) | Missense Mutation (SNP) | VAF 138/310 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200155993; called by muse, varscan2
- FOLR2 | c.-22C>T | Splice Region (SNP) | VAF 174/432 reads (40%) | catalogued as COSV99995443; called by muse, varscan2
- FOXA3 | c.146C>T p.P49L | Missense Mutation (SNP) | VAF 486/608 reads (80%) | SIFT deleterious (0.04); PolyPhen benign (0.136); catalogued as COSV100141301; called by muse, varscan2
- FRG2C | c.67C>T p.P23S | Missense Mutation (SNP) | VAF 172/825 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0.023); catalogued as COSV57316456; called by muse, varscan2
- FURIN | c.107T>C p.V36A | Missense Mutation (SNP) | VAF 164/348 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.224); catalogued as COSV99184674; called by muse, mutect2, varscan2
- GABRE | c.430G>A p.G144S | Missense Mutation (SNP) | VAF 435/435 reads (100%) | SIFT tolerated (1); PolyPhen benign (0.411); catalogued as COSV100944197; called by muse, mutect2, varscan2
- GIPC3 | c.1378G>A p.E460K | Missense Mutation (SNP) | VAF 432/474 reads (91%) | SIFT tolerated (0.45); PolyPhen benign (0.013); catalogued as rs1294965399; called by muse, mutect2, varscan2
- GIPC3 | c.1486G>A p.E496K | Missense Mutation (SNP) | VAF 75/487 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.307); catalogued as COSV100461183; called by muse, varscan2
- GJB3 | c.533T>A p.I178N | Missense Mutation (SNP) | VAF 278/629 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV64904835; called by muse, varscan2
- GLB1L3 | c.1070G>A p.G357E | Missense Mutation (SNP) | VAF 139/316 reads (44%) | SIFT tolerated (0.72); PolyPhen benign (0.02); catalogued as COSV66280825; called by muse, varscan2
- GPATCH2L | c.1081C>T p.P361S | Missense Mutation (SNP) | VAF 194/388 reads (50%) | SIFT tolerated (0.42); PolyPhen benign (0.047); catalogued as rs754927074; called by muse, mutect2, varscan2
- GRIA1 | c.222C>T p.F74= | Splice Region (SNP) | VAF 184/184 reads (100%) | catalogued as COSV53596194; called by muse, mutect2, varscan2
- GSE1 | c.781C>T p.P261S | Missense Mutation (SNP) | VAF 415/415 reads (100%) | SIFT tolerated (0.25); PolyPhen benign (0.071); catalogued as rs150332530; called by muse, mutect2, varscan2
- HTR1A | c.574G>A p.D192N | Missense Mutation (SNP) | VAF 343/344 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs954828937; called by muse, varscan2
- HTR3A | c.847G>C p.G283R | Missense Mutation (SNP) | VAF 207/462 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV55470567; called by muse, mutect2, varscan2
- HTR5A | c.199C>T p.R67C | Missense Mutation (SNP) | VAF 380/718 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs751769358, COSV55283961, COSV99840023; called by muse, varscan2
- HUNK | c.550C>T p.H184Y | Missense Mutation (SNP) | VAF 147/246 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1179104958; called by muse, mutect2, varscan2
- ICE1 | c.6067C>T p.P2023S | Missense Mutation (SNP) | VAF 116/243 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99663811; called by muse, mutect2, varscan2
- IDH2 | c.886C>A p.Q296K | Missense Mutation (SNP) | VAF 166/332 reads (50%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.947); catalogued as COSV51565752; called by muse, varscan2
- IGF1 | c.251G>A p.R84Q | Missense Mutation (SNP) | VAF 260/461 reads (56%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs1565970471, CM096029, COSV61033693; called by muse, mutect2, varscan2
- IGFN1 | c.404C>T p.P135L | Missense Mutation (SNP) | VAF 88/276 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.553); catalogued as rs368275026; called by muse, mutect2, varscan2
- IGHE | c.880G>A p.G294R | Missense Mutation (SNP) | VAF 393/858 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs1318124445; called by muse, varscan2
- IGHMBP2 | c.2255C>T p.S752F | Missense Mutation (SNP) | VAF 227/419 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV54825170; called by muse, mutect2, varscan2
- IMPDH1 | c.790C>T p.Q264* (on ENST00000470772 / NM_001142573.2; = p.Q350* on NM_000883.4) | Nonsense Mutation (SNP) | VAF 173/376 reads (46%) | catalogued as rs1218568607, COSV100118825; called by muse, mutect2, varscan2
- IPO7 | c.2491C>T p.L831F | Missense Mutation (SNP) | VAF 92/141 reads (65%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.964); catalogued as rs1323483608, COSV65686656; called by muse, varscan2
- IRF2BP1 | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 98/490 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56193324; called by muse, varscan2
- IVL | c.785A>C p.Q262P | Missense Mutation (SNP) | VAF 181/673 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV64215719; called by muse, varscan2
- KCNJ3 | c.1495C>T p.R499C | Missense Mutation (SNP) | VAF 137/258 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as rs1239359925, COSV54534586, COSV54540423; called by muse, mutect2, varscan2
- KERA | c.956G>A p.G319E | Missense Mutation (SNP) | VAF 249/441 reads (56%) | SIFT tolerated (0.28); PolyPhen benign (0.187); catalogued as rs760337736; called by muse, mutect2, varscan2
- KIAA2012 | c.1543dup p.S515Kfs*3 | Frame Shift Ins (INS) | VAF 210/504 reads (42%) | catalogued as rs1056854543; called by mutect2, varscan2
- KLHL13 | c.1888C>T p.R630C | Missense Mutation (SNP) | VAF 317/317 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV53245841; called by muse, mutect2, varscan2
- KMT2C | c.9181C>T p.Q3061* | Nonsense Mutation (SNP) | VAF 284/538 reads (53%) | catalogued as COSV51516492, COSV51520902; called by muse, varscan2
- KMT2D | c.9941C>T p.S3314F | Missense Mutation (SNP) | VAF 404/684 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.033); catalogued as rs1258642596, COSV56407832; called by muse, mutect2, varscan2
- KSR2 | c.596C>T p.P199L | Missense Mutation (SNP) | VAF 445/783 reads (57%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV100350448; called by muse, varscan2
- LAMC3 | c.1609G>A p.E537K | Missense Mutation (SNP) | VAF 238/586 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs1011715171; called by muse, varscan2
- LRP10 | c.1484C>T p.S495F | Missense Mutation (SNP) | VAF 244/596 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62078056; called by muse, mutect2, varscan2
- LRP1B | c.4934C>T p.S1645L | Missense Mutation (SNP) | VAF 63/189 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs375614524; called by muse, mutect2, varscan2
- MAGEB16 | c.892C>T p.H298Y | Missense Mutation (SNP) | VAF 394/395 reads (100%) | SIFT deleterious (0.02); PolyPhen benign (0.052); catalogued as rs370569797, COSV67874447; called by muse, varscan2
- MAPT | c.2276G>A p.G759E (on ENST00000262410 / NM_001377265.1; = p.G367E on NM_005910.5) | Missense Mutation (SNP) | VAF 119/420 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52244905; called by muse, mutect2, varscan2
- MCM6 | c.314C>T p.P105L | Missense Mutation (SNP) | VAF 201/463 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as rs1291101798; called by muse, mutect2, varscan2
- MEA1 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 136/407 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.341); catalogued as rs1435435878; called by muse, mutect2, varscan2
- MGAM2 | c.2719C>T p.P907S | Missense Mutation (SNP) | VAF 242/526 reads (46%) | SIFT tolerated (0.3); PolyPhen benign (0.093); catalogued as rs1469143931; called by muse, varscan2
- MMP16 | c.1123G>A p.D375N | Missense Mutation (SNP) | VAF 230/397 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as COSV54188081, COSV99688787; called by muse, mutect2, varscan2
- MROH1 | c.4352C>T p.A1451V | Missense Mutation (SNP) | VAF 271/516 reads (53%) | SIFT tolerated (0.09); PolyPhen benign (0.099); catalogued as rs920515598; called by muse, mutect2, varscan2
- MYH10 | c.160C>T p.R54W | Missense Mutation (SNP) | VAF 329/330 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as rs377262737, COSV52614320; called by muse, varscan2
- MYH13 | c.931G>A p.D311N | Missense Mutation (SNP) | VAF 293/294 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs371327620; called by muse, mutect2, varscan2
- MYO1A | c.1802C>T p.S601F | Missense Mutation (SNP) | VAF 273/454 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.678); catalogued as rs774478942; called by muse, mutect2, varscan2
- MYO5A | c.3361G>A p.E1121K | Missense Mutation (SNP) | VAF 103/215 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.107); catalogued as rs770697352, COSV62560722; called by muse, mutect2, varscan2
- N4BP3 | c.682G>A p.G228R | Missense Mutation (SNP) | VAF 590/592 reads (100%) | SIFT tolerated (0.12); PolyPhen benign (0.019); catalogued as COSV51062210; called by muse, varscan2
- NEB | c.2141G>A p.G714E | Missense Mutation (SNP) | VAF 141/282 reads (50%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV51432175; called by muse, mutect2, varscan2
- NEFL | c.1443G>T p.K481N | Missense Mutation (SNP) | VAF 280/280 reads (100%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV99648015; called by muse, varscan2
- NHSL2 | c.1454C>T p.A485V (on ENST00000510661; = p.A851V on NM_001013627.2) | Missense Mutation (SNP) | VAF 186/186 reads (100%) | SIFT tolerated (0.45); PolyPhen benign (0.052); catalogued as rs868409862; called by muse, varscan2
- NIPAL1 | c.606G>A p.M202I | Missense Mutation (SNP) | VAF 172/172 reads (100%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as COSV55006003; called by muse, mutect2, varscan2
- NISCH | c.4133C>T p.S1378F | Missense Mutation (SNP) | VAF 324/532 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as rs139206974; called by muse, mutect2, varscan2
- NOS2 | c.3403G>A p.E1135K | Missense Mutation (SNP) | VAF 292/638 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs1378739633, COSV104402636; called by muse, mutect2, varscan2
- NPAS2 | c.1769C>T p.S590F | Missense Mutation (SNP) | VAF 240/555 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as rs754493741; called by muse, mutect2, varscan2
- NR1D1 | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 332/516 reads (64%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.483); catalogued as COSV52844176; called by muse, varscan2
- OR10K1 | c.884A>G p.K295R | Missense Mutation (SNP) | VAF 13/407 reads (3%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV56872679, COSV56875021; called by muse, mutect2
- OR1D5 | c.194A>G p.N65S | Missense Mutation (SNP) | VAF 110/225 reads (49%) | SIFT tolerated (0.05); PolyPhen benign (0.06); catalogued as rs754341548; called by muse, varscan2
- OR2G6 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 63/220 reads (29%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV100598070; called by muse, mutect2, varscan2
- OR4A16 | c.116G>A p.G39E | Missense Mutation (SNP) | VAF 198/360 reads (55%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.931); catalogued as rs267602960, COSV59042565, COSV59042689; called by muse, mutect2, varscan2
- OR4C15 | c.790T>G p.F264V (on ENST00000314644; = p.F210V on NM_001001920.2) | Missense Mutation (SNP) | VAF 126/344 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.841); catalogued as COSV58952521; called by muse, mutect2, varscan2
- OR8B2 | c.20C>T p.S7F | Missense Mutation (SNP) | VAF 139/352 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV100899383, COSV66664152; called by muse, varscan2
- OR8J3 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 186/356 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.163); catalogued as COSV56879900; called by muse, mutect2, varscan2
- OTOG | c.745G>T p.G249C | Missense Mutation (SNP) | VAF 180/358 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs914926596, COSV68041396; called by muse, varscan2
- OTOG | c.746G>T p.G249V | Missense Mutation (SNP) | VAF 181/358 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1034866081; called by muse, varscan2
- OTOGL | c.4772C>T p.P1591L (on ENST00000547103; = p.P1582L on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 187/324 reads (58%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as COSV54015002; called by muse, mutect2, varscan2
- OXR1 | c.997G>A p.E333K (on ENST00000442977 / NM_001198532.1; = p.E332K on NM_018002.3) | Missense Mutation (SNP) | VAF 190/534 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.352); catalogued as COSV56323771; called by muse, mutect2, varscan2
- PADI6 | c.530C>T p.T177I | Missense Mutation (SNP) | VAF 203/388 reads (52%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as rs1415465623; called by muse, mutect2, varscan2
- PDGFRB | c.3211G>A p.E1071K | Missense Mutation (SNP) | VAF 532/535 reads (99%) | SIFT deleterious (0.03); PolyPhen benign (0.091); catalogued as COSV53839666; called by muse, mutect2, varscan2
- PDGFRB | c.752G>A p.R251H | Missense Mutation (SNP) | VAF 316/316 reads (100%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.947); catalogued as rs754451292, COSV55801133; called by muse, varscan2
- PGLYRP4 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 122/464 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs750203517; called by muse, mutect2
- PKHD1L1 | c.3100C>T p.R1034C | Missense Mutation (SNP) | VAF 181/294 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs757015646, COSV65743461; called by muse, mutect2, varscan2
- PNLIPRP3 | c.822C>A p.F274L | Missense Mutation (SNP) | VAF 34/217 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.102); catalogued as COSV65047071, COSV65047249; called by muse, mutect2, varscan2
- PTPRK | c.1912C>G p.H638D | Missense Mutation (SNP) | VAF 221/612 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV63905275; called by muse, mutect2, varscan2
- PYHIN1 | c.631C>T p.R211* | Nonsense Mutation (SNP) | VAF 172/282 reads (61%) | catalogued as rs144716673; called by muse, varscan2
- RAG2 | c.601C>A p.Q201K | Missense Mutation (SNP) | VAF 139/353 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as COSV57557131; called by muse, mutect2, varscan2
- REG3G | c.365G>A p.W122* | Nonsense Mutation (SNP) | VAF 204/477 reads (43%) | catalogued as rs1254267404; called by muse, mutect2, varscan2
- RET | c.1375G>A p.E459K | Missense Mutation (SNP) | VAF 488/725 reads (67%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs539995816, COSV60704171; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RIPK3 | c.1226C>T p.P409L | Missense Mutation (SNP) | VAF 237/487 reads (49%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.772); catalogued as COSV99353514; called by muse, mutect2, varscan2
- RNF114 | c.226C>T p.R76* | Nonsense Mutation (SNP) | VAF 383/821 reads (47%) | catalogued as rs773173342, COSV54869485, COSV99724797; called by muse, mutect2, varscan2
- SDHB | c.423C>T p.P141= | Splice Region (SNP) | VAF 124/283 reads (44%) | catalogued as rs150542357; ClinVar: uncertain significance / likely benign; called by muse, varscan2
- SHANK2 | c.3385G>A p.E1129K | Missense Mutation (SNP) | VAF 214/477 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.631); catalogued as rs782565293, COSV99574559, COSV99575388; called by muse, varscan2
- SHANK2 | c.2464G>A p.A822T | Missense Mutation (SNP) | VAF 132/302 reads (44%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.679); catalogued as rs781983283, COSV53591658; called by muse, varscan2
- SI | c.4801C>T p.H1601Y | Missense Mutation (SNP) | VAF 192/192 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV52265690, COSV52283499; called by muse, mutect2, varscan2
- SIN3B | c.1516C>T p.R506C | Missense Mutation (SNP) | VAF 322/322 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1418982296, COSV99931767; called by muse, varscan2
- SLC12A3 | c.1906G>A p.D636N | Missense Mutation (SNP) | VAF 132/372 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV52632921; called by muse, mutect2, varscan2
- SLC18A1 | c.419G>A p.G140E | Missense Mutation (SNP) | VAF 220/220 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375509247; called by muse, varscan2
- SLC1A6 | c.1666G>A p.G556R | Missense Mutation (SNP) | VAF 348/348 reads (100%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV55669361; called by muse, varscan2
- SLC22A10 | c.221G>A p.R74K | Missense Mutation (SNP) | VAF 129/291 reads (44%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.607); catalogued as COSV60422580; called by muse, varscan2
- SLC28A2 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 96/183 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.169); catalogued as rs370809865; called by muse, mutect2, varscan2
- SLC39A11 | c.560G>A p.G187D (on ENST00000542342 / NM_001159770.2; = p.G180D on NM_139177.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 432/662 reads (65%) | SIFT tolerated (0.24); PolyPhen benign (0.094); catalogued as COSV55290849; called by muse, varscan2
- SLC6A1 | c.1324G>A p.G442R | Missense Mutation (SNP) | VAF 78/245 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747554856; called by muse, mutect2, varscan2
- SLC9A2 | c.1348C>T p.P450S | Missense Mutation (SNP) | VAF 276/602 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.722); catalogued as rs1257344491; called by muse, varscan2
- SLCO5A1 | c.1123C>T p.R375* | Nonsense Mutation (SNP) | VAF 112/370 reads (30%) | catalogued as rs200135889; called by muse, varscan2
- SNAP25 | c.245G>A p.G82E | Missense Mutation (SNP) | VAF 202/345 reads (59%) | SIFT tolerated (1); PolyPhen benign (0.367); catalogued as rs866969321, COSV54770798, COSV54771307; called by muse, mutect2, varscan2
- SNAP91 | c.2429C>T p.P810L | Missense Mutation (SNP) | VAF 130/396 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as COSV99056321; called by muse, mutect2, varscan2
- SPATA2 | c.1142C>T p.S381F | Missense Mutation (SNP) | VAF 418/772 reads (54%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.595); catalogued as rs768360443; called by muse, varscan2
- SPEN | c.7232C>T p.S2411L | Missense Mutation (SNP) | VAF 337/694 reads (49%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as COSV65359735; called by muse, mutect2, varscan2
- SPIC | c.239G>A p.G80E | Missense Mutation (SNP) | VAF 195/364 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as COSV54690911; called by muse, mutect2, varscan2
- SPIDR | c.2506T>C p.F836L | Missense Mutation (SNP) | VAF 300/302 reads (99%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as rs1456545446; called by muse, mutect2, varscan2
- TAF4B | c.796C>T p.L266F | Missense Mutation (SNP) | VAF 120/214 reads (56%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs1464918681, COSV99299951; called by muse, varscan2
- TANC1 | c.2902G>T p.G968C | Missense Mutation (SNP) | VAF 234/502 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55086025; called by muse, varscan2
- TDRD5 | c.950C>T p.S317F | Missense Mutation (SNP) | VAF 199/303 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV54239472; called by muse, mutect2, varscan2
- TET3 | c.2891G>A p.R964Q | Missense Mutation (SNP) | VAF 187/375 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1558784441; called by muse, mutect2, varscan2
- THSD4 | c.2665G>A p.V889M | Missense Mutation (SNP) | VAF 140/304 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as COSV55977991; called by muse, varscan2
- TIGD2 | c.880C>T p.P294S | Missense Mutation (SNP) | VAF 101/367 reads (28%) | SIFT tolerated (0.49); PolyPhen benign (0.024); catalogued as rs766258790; called by muse, mutect2, varscan2
- TLDC2 | c.328G>A p.D110N | Missense Mutation (SNP) | VAF 218/345 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs571259365; called by muse, mutect2, varscan2
- TMCO4 | c.1156C>T p.H386Y | Missense Mutation (SNP) | VAF 249/496 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.805); catalogued as rs766175122; called by muse, mutect2, varscan2
- TMEM178B | c.772G>A p.G258S | Missense Mutation (SNP) | VAF 159/443 reads (36%) | SIFT tolerated (1); PolyPhen probably damaging (0.988); catalogued as rs1382629290; called by muse, mutect2, varscan2
- TMEM178B | c.773G>A p.G258D | Missense Mutation (SNP) | VAF 158/440 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV73805201; called by muse, mutect2, varscan2
- TNR | c.3002G>A p.G1001E | Missense Mutation (SNP) | VAF 166/270 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV54902798; called by muse, varscan2
- TNRC6A | c.4837C>T p.R1613C | Missense Mutation (SNP) | VAF 124/270 reads (46%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.996); catalogued as rs1050271217, COSV59370018; called by muse, mutect2, varscan2
- TP53 | c.1006G>T p.E336* | Nonsense Mutation (SNP) | VAF 297/297 reads (100%) | catalogued as CM044725, COSV52746809, COSV52814837, COSV53366474; called by muse, mutect2, varscan2
- TRAV10 | c.109G>A p.G37R | Missense Mutation (SNP) | VAF 252/474 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1270200265; called by muse, varscan2
- TTC6 | c.3377G>A p.R1126Q | Missense Mutation (SNP) | VAF 219/427 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs1566954798; called by muse, mutect2, varscan2
- TTN | c.33217G>A p.E11073K (on ENST00000591111; = p.E10146K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 280/630 reads (44%) | PolyPhen benign (0.154); catalogued as COSV60169091; called by muse, mutect2, varscan2
- WSCD2 | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 205/491 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.435); catalogued as COSV54581564; called by muse, mutect2, varscan2
- XIRP2 | c.9182C>T p.P3061L (on ENST00000628543; = p.P3236L on NM_152381.6) | Missense Mutation (SNP) | VAF 265/502 reads (53%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.981); catalogued as rs375611135, COSV99747455; called by muse, varscan2
- ZAR1L | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 174/402 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs977237682, COSV61525501; called by muse, varscan2
- ZFHX4 | c.1022C>T p.S341F | Missense Mutation (SNP) | VAF 216/616 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.66); catalogued as rs267601996, COSV50578199; called by muse, mutect2, varscan2
- ZKSCAN3 | c.179C>T p.P60L | Missense Mutation (SNP) | VAF 320/584 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99357110; called by muse, varscan2
- ZNF717 | c.1885C>T p.R629C | Missense Mutation (SNP) | VAF 119/809 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1420497827; called by muse, varscan2
- ZSCAN4 | c.1163G>A p.R388K | Missense Mutation (SNP) | VAF 102/346 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.942); catalogued as COSV56595348; called by muse, mutect2, varscan2
- ADAMTS17 | c.1267C>T p.P423S | Missense Mutation (SNP) | VAF 155/307 reads (50%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAMTS20 | c.2494G>A p.D832N | Missense Mutation (SNP) | VAF 167/288 reads (58%) | SIFT tolerated (0.2); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- ADCY7 | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 388/613 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, varscan2
- AGO4 | c.937C>T p.P313S | Missense Mutation (SNP) | VAF 263/541 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.634); called by muse, mutect2, varscan2
- AHNAK | c.6883_6884dup p.K2296* | Frame Shift Ins (INS) | VAF 120/428 reads (28%) | called by pindel, varscan2
- AK9 | c.3503G>A p.W1168* | Nonsense Mutation (SNP) | VAF 128/331 reads (39%) | called by muse, mutect2, varscan2
- ALDH3A2 | c.1131G>C p.E377D | Missense Mutation (SNP) | VAF 279/279 reads (100%) | SIFT deleterious (0.02); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- ANGEL1 | c.1123C>T p.P375S | Missense Mutation (SNP) | VAF 328/576 reads (57%) | SIFT tolerated (0.11); PolyPhen benign (0.298); called by muse, varscan2
- ANHX | c.1124G>A p.G375E | Missense Mutation (SNP) | VAF 220/403 reads (55%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.880C>T p.H294Y | Missense Mutation (SNP) | VAF 261/261 reads (100%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ANKIB1 | c.2299C>T p.Q767* | Nonsense Mutation (SNP) | VAF 152/408 reads (37%) | called by muse, varscan2
- AP3D1 | c.1978_1980delinsCA p.A660Qfs*54 | Frame Shift Del (DEL) | VAF 293/641 reads (46%) | called by pindel, varscan2*
- ARAP1 | c.719G>A p.G240E | Missense Mutation (SNP) | VAF 236/447 reads (53%) | SIFT tolerated (0.95); PolyPhen benign (0.07); called by muse, varscan2
- ARFGAP3 | c.1010C>T p.P337L | Missense Mutation (SNP) | VAF 136/382 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.293); called by muse, varscan2
- B4GALNT2 | c.1226C>T p.T409I | Missense Mutation (SNP) | VAF 106/410 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, varscan2
- BTBD7 | c.2665C>T p.P889S | Missense Mutation (SNP) | VAF 296/726 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- C12orf4 | c.109C>T p.Q37* | Nonsense Mutation (SNP) | VAF 173/501 reads (35%) | called by muse, mutect2, varscan2
- C14orf39 | c.1398A>T p.E466D | Missense Mutation (SNP) | VAF 132/289 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- C16orf78 | c.400G>A p.D134N | Missense Mutation (SNP) | VAF 225/339 reads (66%) | SIFT tolerated (0.06); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- C2CD6 | c.1600G>A p.E534K | Missense Mutation (SNP) | VAF 112/221 reads (51%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- CASZ1 | c.1274C>T p.P425L | Missense Mutation (SNP) | VAF 264/558 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.382); called by muse, varscan2
- CDH16 | c.80T>A p.V27E | Missense Mutation (SNP) | VAF 299/452 reads (66%) | SIFT deleterious (0); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- CEP76 | c.1975T>A p.L659I | Missense Mutation (SNP) | VAF 198/198 reads (100%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- CFAP54 | c.8705C>T p.S2902F | Missense Mutation (SNP) | VAF 160/277 reads (58%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.711); called by muse, mutect2, varscan2
- CLEC10A | c.520+6G>A | Splice Region (SNP) | VAF 210/210 reads (100%) | called by muse, mutect2, varscan2
- CNTN5 | c.2270G>A p.G757E | Missense Mutation (SNP) | VAF 150/314 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL1A1 | c.1742G>A p.G581E | Missense Mutation (SNP) | VAF 133/432 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL4A5 | c.3453A>G p.V1151= | Splice Region (SNP) | VAF 240/240 reads (100%) | called by muse, mutect2, varscan2
- COL4A5 | c.4195C>T p.P1399S | Missense Mutation (SNP) | VAF 221/221 reads (100%) | SIFT tolerated (0.5); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- CORO7 | c.1493C>T p.P498L | Missense Mutation (SNP) | VAF 379/629 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- CREG1 | c.424C>T p.P142S | Missense Mutation (SNP) | VAF 242/356 reads (68%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CRIM1 | c.1397C>T p.P466L | Missense Mutation (SNP) | VAF 163/341 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CTNND2 | c.2544A>C p.K848N | Missense Mutation (SNP) | VAF 139/704 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- DDC | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 195/301 reads (65%) | SIFT tolerated (0.89); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- DGKH | c.3536G>A p.G1179E | Missense Mutation (SNP) | VAF 99/167 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- DIS3L2 | c.1534G>C p.E512Q | Missense Mutation (SNP) | VAF 259/532 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- DNAH3 | c.5632G>A p.E1878K | Missense Mutation (SNP) | VAF 118/213 reads (55%) | SIFT tolerated (0.12); PolyPhen benign (0.105); called by muse, varscan2
- DNAH8 | c.11185C>T p.P3729S | Missense Mutation (SNP) | VAF 100/189 reads (53%) | SIFT tolerated (0.2); PolyPhen benign (0.009); called by muse, varscan2
- DOCK3 | c.1004A>G p.K335R | Missense Mutation (SNP) | VAF 194/306 reads (63%) | SIFT tolerated (0.32); PolyPhen benign (0.007); called by muse, varscan2
- DOK6 | c.347T>G p.L116R | Missense Mutation (SNP) | VAF 82/458 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.52); called by muse, mutect2, varscan2
- DRC1 | c.1791A>T p.E597D | Missense Mutation (SNP) | VAF 204/492 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, varscan2
- DYNC1I1 | c.606G>C p.Q202H | Missense Mutation (SNP) | VAF 75/415 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- DYNC2I1 | c.1598T>C p.V533A | Missense Mutation (SNP) | VAF 140/326 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- ENOSF1 | c.1094G>A p.R365K (on ENST00000340116 / NM_001354066.2; = p.R331K on NM_017512.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 231/232 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EPPK1 | c.2102C>T p.S701F | Missense Mutation (SNP) | VAF 405/897 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EVPL | c.917C>T p.A306V | Missense Mutation (SNP) | VAF 108/402 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, varscan2
- FAT3 | c.5929G>A p.D1977N | Missense Mutation (SNP) | VAF 144/304 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, varscan2
- FAT3 | c.7213G>A p.E2405K | Missense Mutation (SNP) | VAF 142/321 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, varscan2
- FFAR3 | c.364T>C p.W122R | Missense Mutation (SNP) | VAF 111/471 reads (24%) | SIFT tolerated (0.83); PolyPhen benign (0.042); called by muse, varscan2
- FLNB | c.6983G>A p.G2328E | Missense Mutation (SNP) | VAF 155/438 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FLT1 | c.3721G>A p.D1241N | Missense Mutation (SNP) | VAF 82/173 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- GGT7 | c.161C>T p.P54L | Missense Mutation (SNP) | VAF 196/333 reads (59%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); called by muse, varscan2
- GGT7 | c.160C>T p.P54S | Missense Mutation (SNP) | VAF 202/344 reads (59%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.025); called by muse, varscan2
- GLUD1 | c.447T>C p.G149= | Splice Region (SNP) | VAF 67/211 reads (32%) | called by muse, mutect2, varscan2
- GOLGA6L9 | c.91G>C p.A31P | Missense Mutation (SNP) | VAF 53/264 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- GRIA1 | c.967T>C p.C323R | Missense Mutation (SNP) | VAF 380/380 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GTPBP3 | c.892C>T p.P298S | Missense Mutation (SNP) | VAF 552/552 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- HECW2 | c.604T>C p.F202L | Missense Mutation (SNP) | VAF 225/400 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, varscan2
- HNRNPH1 | c.113A>G p.N38S | Missense Mutation (SNP) | VAF 300/302 reads (99%) | SIFT deleterious (0.05); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- IGHE | c.881G>A p.G294E | Missense Mutation (SNP) | VAF 389/858 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, varscan2
- IGHG1 | c.367G>A p.V123I | Missense Mutation (SNP) | VAF 304/696 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.031); called by muse, varscan2
- IL17RC | c.1180C>T p.P394S (on ENST00000295981 / NM_153461.4; = p.P308S on NM_032732.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 243/687 reads (35%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.69); called by muse, mutect2
- IL17RC | c.1181C>T p.P394L (on ENST00000295981 / NM_153461.4; = p.P308L on NM_032732.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 244/686 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0.018); called by muse, mutect2
- INPP5B | c.1799C>T p.P600L (on ENST00000373023; = p.P520L on NM_005540.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 161/329 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- INSRR | c.52C>T p.L18F | Missense Mutation (SNP) | VAF 143/393 reads (36%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- IQCM | c.794T>G p.V265G | Missense Mutation (SNP) | VAF 100/315 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- ITGA7 | c.3425C>T p.T1142I (on ENST00000555728; = p.T1098I on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 446/743 reads (60%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.661); called by muse, mutect2, varscan2
- KCND3 | c.911C>T p.S304F | Missense Mutation (SNP) | VAF 330/614 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KDM4F | c.115G>A p.G39S | Missense Mutation (SNP) | VAF 160/344 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- KDM4F | c.116G>A p.G39D | Missense Mutation (SNP) | VAF 162/344 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- KDM5A | c.856C>T p.L286F | Missense Mutation (SNP) | VAF 232/399 reads (58%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- KLHL29 | c.1962G>A p.W654* | Nonsense Mutation (SNP) | VAF 202/482 reads (42%) | called by muse, mutect2, varscan2
- KNTC1 | c.1617G>A p.W539* | Nonsense Mutation (SNP) | VAF 85/246 reads (35%) | called by muse, mutect2, varscan2
- KRTAP29-1 | c.271T>C p.C91R | Missense Mutation (SNP) | VAF 214/841 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); called by muse, varscan2
- LAMC2 | c.3053C>T p.S1018F | Missense Mutation (SNP) | VAF 191/305 reads (63%) | SIFT deleterious (0.04); PolyPhen benign (0.202); called by muse, mutect2
- LLGL1 | c.2450C>T p.P817L | Missense Mutation (SNP) | VAF 454/454 reads (100%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LMTK3 | c.2234C>T p.P745L | Missense Mutation (SNP) | VAF 127/153 reads (83%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.181); called by muse, mutect2, varscan2
- LRRTM4 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 186/424 reads (44%) | SIFT tolerated (0.37); PolyPhen benign (0.044); called by muse, varscan2
- LY75 | c.720G>T p.W240C | Missense Mutation (SNP) | VAF 207/394 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- MAGEC1 | c.1822C>T p.P608S | Missense Mutation (SNP) | VAF 487/490 reads (99%) | SIFT tolerated, low confidence (0.16); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- MDN1 | c.7253C>T p.S2418F | Missense Mutation (SNP) | VAF 204/370 reads (55%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- MDN1 | c.1246C>T p.P416S | Missense Mutation (SNP) | VAF 199/300 reads (66%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.537); called by muse, mutect2, varscan2
- MED12 | c.3314A>G p.N1105S | Missense Mutation (SNP) | VAF 375/375 reads (100%) | SIFT tolerated (0.3); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- MIB2 | c.169C>G p.L57V | Missense Mutation (SNP) | VAF 208/446 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- MMP19 | c.691G>A p.A231T | Missense Mutation (SNP) | VAF 275/486 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- MMP19 | c.690G>A p.M230I | Missense Mutation (SNP) | VAF 274/485 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- MTX1 | c.427C>T p.P143S | Missense Mutation (SNP) | VAF 493/778 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MUC4 | c.12852dup p.T4285Hfs*29 (on ENST00000463781 / NM_018406.7; = p.T49Hfs*29 on NM_004532.6) | Frame Shift Ins (INS) | VAF 500/1470 reads (34%) | called by mutect2, pindel, varscan2
- MUC4 | c.4996C>T p.P1666S | Missense Mutation (SNP) | VAF 505/1635 reads (31%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.65); called by muse, varscan2
- MYO9A | c.7403C>T p.A2468V | Missense Mutation (SNP) | VAF 124/236 reads (53%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); called by muse, varscan2
- NAV2 | c.6473C>T p.P2158L (on ENST00000396087 / NM_001244963.2; = p.P2099L on NM_145117.5) | Missense Mutation (SNP) | VAF 195/375 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NBEA | c.863G>A p.G288E | Missense Mutation (SNP) | VAF 67/157 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NLRP2 | c.1411G>A p.E471K | Missense Mutation (SNP) | VAF 613/819 reads (75%) | SIFT tolerated (0.89); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- NLRP6 | c.2221C>T p.P741S | Missense Mutation (SNP) | VAF 134/389 reads (34%) | SIFT tolerated (0.65); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- NOTCH4 | c.2622G>A p.W874* | Nonsense Mutation (SNP) | VAF 323/892 reads (36%) | called by muse, mutect2, varscan2
- NPIPA5 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 75/310 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, varscan2
- OR1B1 | c.547T>G p.F183V | Missense Mutation (SNP) | VAF 170/812 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, varscan2
- OR6C65 | c.722C>T p.S241F | Missense Mutation (SNP) | VAF 176/461 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- OR8B2 | c.398A>T p.K133M | Missense Mutation (SNP) | VAF 189/419 reads (45%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.594); called by muse, mutect2, varscan2
- PADI4 | c.1084A>T p.K362* | Nonsense Mutation (SNP) | VAF 238/470 reads (51%) | called by mutect2, varscan2
- PCDHB8 | c.1196G>A p.G399E | Missense Mutation (SNP) | VAF 332/332 reads (100%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, varscan2
- PCDHGA4 | c.1462T>A p.Y488N | Missense Mutation (SNP) | VAF 410/411 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- PIGH | c.226C>A p.L76M | Missense Mutation (SNP) | VAF 207/371 reads (56%) | SIFT tolerated (0.35); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- POU2F3 | c.140C>T p.T47I | Missense Mutation (SNP) | VAF 82/239 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, varscan2
- PPP3CA | c.1048T>A p.F350I | Missense Mutation (SNP) | VAF 351/351 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPP4R3A | c.1325T>C p.L442P (on ENST00000554943 / NM_001366432.1; = p.L429P on NM_001284280.1) | Missense Mutation (SNP) | VAF 221/464 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- PSPC1 | c.173_222del p.D58Gfs*57 | Frame Shift Del (DEL) | VAF 128/406 reads (32%) | called by pindel, varscan2
- PTHLH | c.143G>A p.G48E | Missense Mutation (SNP) | VAF 226/381 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- PTHLH | c.142G>A p.G48R | Missense Mutation (SNP) | VAF 228/385 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- RASIP1 | c.2453G>A p.G818E | Missense Mutation (SNP) | VAF 41/360 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.8); called by muse, varscan2
- RHBDL3 | c.941G>T p.C314F | Missense Mutation (SNP) | VAF 237/390 reads (61%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RIMS1 | c.3875C>G p.T1292R | Missense Mutation (SNP) | VAF 96/347 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- RIPOR2 | c.890T>G p.V297G | Missense Mutation (SNP) | VAF 298/471 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- RNASE12 | c.373C>T p.P125S | Missense Mutation (SNP) | VAF 192/484 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- RNF186 | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 304/676 reads (45%) | SIFT tolerated (0.56); PolyPhen benign (0.003); called by muse, varscan2
- RNF213 | c.1159_1165del p.I387Ffs*56 | Frame Shift Del (DEL) | VAF 221/400 reads (55%) | called by mutect2, pindel, varscan2
- RPF1 | c.700-15_715del p.X234_splice | Splice Site (DEL) | VAF 118/349 reads (34%) | called by mutect2, pindel, varscan2
- RUNX3 | c.899C>T p.T300I | Missense Mutation (SNP) | VAF 440/872 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.042); called by muse, varscan2
- RXRA | c.368C>T p.P123L | Missense Mutation (SNP) | VAF 462/1010 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.16); called by muse, varscan2
- SCAF1 | c.1727C>T p.S576F | Missense Mutation (SNP) | VAF 455/522 reads (87%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); called by muse, varscan2
- SCN9A | c.2226G>A p.M742I (on ENST00000303354; = p.M731I on NM_002977.3) | Missense Mutation (SNP) | VAF 191/369 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- SECISBP2 | c.1049C>T p.S350F | Missense Mutation (SNP) | VAF 151/404 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- SERPINB11 | c.1024G>A p.E342K | Missense Mutation (SNP) | VAF 212/584 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SETX | c.7032A>G p.I2344M | Missense Mutation (SNP) | VAF 212/546 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, varscan2
- SLAIN1 | c.242G>A p.R81Q | Missense Mutation (SNP) | VAF 224/413 reads (54%) | SIFT tolerated (0.64); called by muse, varscan2
- SLC12A9 | c.67G>C p.A23P | Missense Mutation (SNP) | VAF 67/907 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2
- SLC2A13 | c.1226C>T p.A409V | Missense Mutation (SNP) | VAF 171/328 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- SLC7A10 | c.482C>T p.S161F | Missense Mutation (SNP) | VAF 42/374 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.574); called by muse, mutect2, varscan2
- SLFN14 | c.993G>A p.M331I | Missense Mutation (SNP) | VAF 268/428 reads (63%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SNX15 | c.889G>A p.D297N | Missense Mutation (SNP) | VAF 206/402 reads (51%) | SIFT tolerated (0.31); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- SPIRE1 | c.1735C>T p.Q579* (on ENST00000409402 / NM_001128626.2; = p.Q565* on NM_020148.3) | Nonsense Mutation (SNP) | VAF 249/249 reads (100%) | called by muse, mutect2, varscan2
- SSTR4 | c.14C>T p.S5L | Missense Mutation (SNP) | VAF 127/396 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, varscan2
- STAB1 | c.391G>A p.D131N | Missense Mutation (SNP) | VAF 152/449 reads (34%) | SIFT tolerated (0.49); PolyPhen benign (0.012); called by muse, varscan2
- STOML3 | c.637G>T p.E213* | Nonsense Mutation (SNP) | VAF 176/304 reads (58%) | called by muse, mutect2
- TBC1D16 | c.1616C>T p.P539L | Missense Mutation (SNP) | VAF 195/587 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TEX44 | c.371T>G p.F124C | Missense Mutation (SNP) | VAF 25/626 reads (4%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.895); called by muse, mutect2
- TIMD4 | c.1111G>A p.D371N | Missense Mutation (SNP) | VAF 347/348 reads (100%) | SIFT deleterious (0.03); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- TMEM260 | c.1589C>T p.P530L | Missense Mutation (SNP) | VAF 125/325 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TNC | c.5276G>A p.G1759E | Missense Mutation (SNP) | VAF 209/532 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, varscan2
- TRAF5 | c.245C>G p.P82R | Missense Mutation (SNP) | VAF 133/386 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- TRPC6 | c.600dup p.L201Tfs*5 | Frame Shift Ins (INS) | VAF 164/428 reads (38%) | called by pindel, varscan2
- TSACC | c.224T>C p.L75P | Missense Mutation (SNP) | VAF 274/447 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- TSPAN10 | c.994T>C p.S332P (on ENST00000574882 / NM_001290212.1; = p.S294P on NM_031945.4) | Missense Mutation (SNP) | VAF 629/957 reads (66%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TSPYL5 | c.389G>A p.G130E | Missense Mutation (SNP) | VAF 294/819 reads (36%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.465); called by muse, varscan2
- TXNRD2 | c.992G>A p.G331E | Missense Mutation (SNP) | VAF 28/463 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2
- UBQLN3 | c.1948G>A p.E650K | Missense Mutation (SNP) | VAF 204/360 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.103); called by muse, mutect2
- UNC5C | c.2674A>C p.I892L | Missense Mutation (SNP) | VAF 128/454 reads (28%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.803); called by muse, varscan2
- USP29 | c.650A>C p.E217A | Missense Mutation (SNP) | VAF 229/323 reads (71%) | SIFT deleterious (0.02); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- UXS1 | c.347C>T p.T116I | Missense Mutation (SNP) | VAF 265/616 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- VIPAS39 | c.1359C>T p.T453= | Splice Region (SNP) | VAF 140/272 reads (51%) | called by muse, mutect2, varscan2
- VN1R2 | c.328T>A p.Y110N | Missense Mutation (SNP) | VAF 265/316 reads (84%) | SIFT deleterious (0.01); PolyPhen benign (0.306); called by muse, varscan2
- XPO7 | c.2068T>C p.F690L | Missense Mutation (SNP) | VAF 168/170 reads (99%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); called by muse, varscan2
- ZBTB21 | c.1625C>T p.P542L | Missense Mutation (SNP) | VAF 118/348 reads (34%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- ZBTB21 | c.1624C>T p.P542S | Missense Mutation (SNP) | VAF 120/349 reads (34%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- ZDHHC5 | c.808C>T p.R270* | Nonsense Mutation (SNP) | VAF 114/264 reads (43%) | called by muse, varscan2
- ZFX | c.193C>T p.Q65* | Nonsense Mutation (SNP) | VAF 337/337 reads (100%) | called by muse, mutect2, varscan2
- ZKSCAN2 | c.2015C>T p.P672L | Missense Mutation (SNP) | VAF 98/284 reads (35%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZMYM2 | c.385C>T p.Q129* | Nonsense Mutation (SNP) | VAF 131/280 reads (47%) | called by muse, varscan2
- ZNF726 | c.964T>A p.F322I | Missense Mutation (SNP) | VAF 306/308 reads (99%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, varscan2
- ABCA13 | c.11889G>A p.V3963= | Silent (SNP) | VAF 71/251 reads (28%) | catalogued as rs1465236321, COSV71294082; called by muse, mutect2, varscan2
- ACE | c.1458C>T p.S486= | Silent (SNP) | VAF 312/471 reads (66%) | catalogued as COSV52004274; called by muse, mutect2, varscan2
- ACHE | c.216C>T p.P72= | Silent (SNP) | VAF 398/727 reads (55%) | catalogued as rs267601194, COSV99573652; called by muse, mutect2, varscan2
- ACY3 | c.306C>T p.P102= | Silent (SNP) | VAF 168/423 reads (40%) | called by muse, mutect2, varscan2
- ADAMTS20 | c.252C>T p.A84= | Silent (SNP) | VAF 220/548 reads (40%) | called by muse, mutect2, varscan2
- ADGRD2 | c.1665C>T p.I555= | Silent (SNP) | VAF 281/660 reads (43%) | called by muse, mutect2, varscan2
- AGT | c.429G>A p.L143= | Silent (SNP) | VAF 302/489 reads (62%) | called by muse, varscan2
- AIRE | c.259C>T p.L87= | Silent (SNP) | VAF 229/390 reads (59%) | called by muse, mutect2, varscan2
- ALG2 | c.1047C>T p.P349= | Silent (SNP) | VAF 228/531 reads (43%) | called by muse, mutect2, varscan2
- ANO2 | c.2829G>A p.V943= (on ENST00000356134 / NM_001278597.3; = p.V947= on NM_001278596.3) | Silent (SNP) | VAF 310/514 reads (60%) | called by muse, varscan2
- ARHGAP5 | c.1923G>A p.S641= | Silent (SNP) | VAF 108/467 reads (23%) | catalogued as rs773413531; called by muse, varscan2
- ASAP3 | c.1704C>T p.A568= | Silent (SNP) | VAF 300/569 reads (53%) | called by muse, varscan2
- ATAD5 | c.2868T>A p.P956= | Silent (SNP) | VAF 155/273 reads (57%) | called by muse, mutect2, varscan2
- CA9 | c.1051C>T p.L351= | Silent (SNP) | VAF 202/202 reads (100%) | called by muse, mutect2, varscan2
- CACNA1H | c.5547C>T p.F1849= | Silent (SNP) | VAF 207/540 reads (38%) | catalogued as rs747094670; called by muse, mutect2, varscan2
- CCDC180 | c.3651C>T p.L1217= | Silent (SNP) | VAF 206/491 reads (42%) | catalogued as rs768861238; called by muse, mutect2, varscan2
- CCDC87 | c.1455C>T p.N485= | Silent (SNP) | VAF 209/379 reads (55%) | called by muse, mutect2, varscan2
- CEMIP | c.1554C>T p.F518= | Silent (SNP) | VAF 138/265 reads (52%) | catalogued as COSV54991814; called by muse, mutect2, varscan2
- CENPE | c.342C>T p.F114= | Silent (SNP) | VAF 87/225 reads (39%) | catalogued as COSV54390238; called by muse, mutect2, varscan2
- CEP85L | c.16C>T p.L6= | Silent (SNP) | VAF 312/531 reads (59%) | called by muse, varscan2
- CEP85L | c.15C>T p.F5= | Silent (SNP) | VAF 313/530 reads (59%) | called by muse, varscan2
- CNOT1 | c.2703T>C p.F901= | Silent (SNP) | VAF 121/368 reads (33%) | called by muse, varscan2
- CNTN4 | c.2892C>T p.F964= | Silent (SNP) | VAF 233/431 reads (54%) | catalogued as rs748149654, COSV61871927; called by muse, mutect2, varscan2
- CNTNAP5 | c.652C>T p.L218= | Silent (SNP) | VAF 183/443 reads (41%) | catalogued as COSV70507989; called by muse, mutect2, varscan2
- CR2 | c.2532C>T p.I844= | Silent (SNP) | VAF 92/278 reads (33%) | called by muse, mutect2, varscan2
- CRTC2 | c.348C>T p.S116= | Silent (SNP) | VAF 118/391 reads (30%) | called by muse, mutect2, varscan2
- CSMD1 | c.4317C>T p.F1439= (on ENST00000520002; = p.F1438= on NM_033225.6) | Silent (SNP) | VAF 214/215 reads (100%) | catalogued as COSV59298436; called by muse, mutect2, varscan2
- CTNND2 | c.2064C>T p.I688= | Silent (SNP) | VAF 228/512 reads (45%) | catalogued as COSV58863113; called by muse, mutect2, varscan2
- CUBN | c.7116A>C p.G2372= | Silent (SNP) | VAF 303/303 reads (100%) | called by muse, mutect2, varscan2
- CYB561 | c.453C>T p.S151= | Silent (SNP) | VAF 327/511 reads (64%) | called by muse, mutect2, varscan2
- CYP2F1 | c.429G>A p.E143= | Silent (SNP) | VAF 249/314 reads (79%) | called by muse, mutect2, varscan2
- CYP4B1 | c.354C>T p.F118= | Silent (SNP) | VAF 244/487 reads (50%) | catalogued as rs867323780; called by muse, mutect2, varscan2
- DCDC1 | c.1302G>A p.K434= | Silent (SNP) | VAF 134/235 reads (57%) | called by muse, varscan2
- DCTN2 | c.700C>T p.L234= (on ENST00000548249 / NM_001261413.2; = p.L239= on NM_006400.4) | Silent (SNP) | VAF 252/418 reads (60%) | called by muse, mutect2, varscan2
- DENND1A | c.2739C>T p.P913= | Silent (SNP) | VAF 430/430 reads (100%) | catalogued as rs752736162; called by muse, varscan2
- DENND1A | c.1104T>C p.I368= | Silent (SNP) | VAF 125/326 reads (38%) | called by muse, mutect2, varscan2
- DHRS11 | c.573C>T p.I191= | Silent (SNP) | VAF 266/375 reads (71%) | called by muse, mutect2, varscan2
- DIDO1 | c.1014T>G p.A338= | Silent (SNP) | VAF 124/380 reads (33%) | called by muse, mutect2, varscan2
- DNAH5 | c.7447C>T p.L2483= | Silent (SNP) | VAF 443/935 reads (47%) | called by muse, mutect2, varscan2
- DNAJA1 | c.1035C>T p.L345= | Silent (SNP) | VAF 239/241 reads (99%) | catalogued as rs1564015672; called by muse, mutect2, varscan2
- DPF3 | c.48C>T p.F16= | Silent (SNP) | VAF 185/387 reads (48%) | called by muse, mutect2, varscan2
- DSCAML1 | c.6309C>T p.A2103= (on ENST00000321322; = p.A2043= on NM_020693.4) | Silent (SNP) | VAF 114/251 reads (45%) | catalogued as rs140170178; called by muse, mutect2, varscan2
- DUOX2 | c.3912G>A p.R1304= | Silent (SNP) | VAF 162/328 reads (49%) | called by muse, mutect2, varscan2
- EFHD1 | c.534C>T p.I178= | Silent (SNP) | VAF 234/599 reads (39%) | catalogued as rs546425742; called by muse, mutect2
- EIF4E1B | c.466C>T p.L156= | Silent (SNP) | VAF 180/344 reads (52%) | called by muse, mutect2, varscan2
- FAM102B | c.462C>T p.S154= | Silent (SNP) | VAF 190/423 reads (45%) | called by muse, mutect2, varscan2
- FAM131C | c.39C>T p.A13= | Silent (SNP) | VAF 194/401 reads (48%) | called by muse, mutect2, varscan2
- FAM209A | c.480G>A p.T160= | Silent (SNP) | VAF 146/384 reads (38%) | catalogued as rs1054364; called by muse, varscan2
- FAM214A | c.39A>G p.E13= | Silent (SNP) | VAF 84/187 reads (45%) | called by muse, mutect2, varscan2
- FAM71D | c.720C>T p.I240= | Silent (SNP) | VAF 195/357 reads (55%) | called by muse, mutect2, varscan2
- FAM83A | c.564C>T p.F188= | Silent (SNP) | VAF 204/482 reads (42%) | catalogued as rs1378116226, COSV52683892; called by muse, varscan2
- FAM90A1 | c.453G>A p.P151= | Silent (SNP) | VAF 268/438 reads (61%) | catalogued as rs771226962, COSV56710105; called by muse, mutect2, varscan2
- FHAD1 | c.1077G>A p.K359= | Silent (SNP) | VAF 165/412 reads (40%) | called by muse, mutect2, varscan2
- FRG1 | c.453C>T p.A151= | Silent (SNP) | VAF 140/394 reads (36%) | called by muse, varscan2
- FZD10 | c.1422C>T p.I474= | Silent (SNP) | VAF 289/698 reads (41%) | catalogued as COSV99969621; called by muse, mutect2, varscan2
- GALNT14 | c.591C>T p.F197= | Silent (SNP) | VAF 303/586 reads (52%) | called by muse, varscan2
- GPR55 | c.573C>A p.L191= | Silent (SNP) | VAF 268/600 reads (45%) | called by muse, mutect2, varscan2
- GPRC5C | c.222C>T p.P74= (on ENST00000652232; = p.P29= on NM_018653.4) | Silent (SNP) | VAF 384/590 reads (65%) | catalogued as rs147345722; called by muse, mutect2, varscan2
- GRM3 | c.237C>A p.I79= | Silent (SNP) | VAF 226/484 reads (47%) | catalogued as COSV100862578; called by mutect2, varscan2
- HCAR2 | c.195C>T p.F65= | Silent (SNP) | VAF 276/674 reads (41%) | catalogued as rs746448105; called by muse, mutect2, varscan2
- HOXB4 | c.585C>T p.I195= | Silent (SNP) | VAF 168/542 reads (31%) | catalogued as rs1394962550, COSV100203839; called by muse, varscan2
- HOXD11 | c.279C>T p.P93= | Silent (SNP) | VAF 110/226 reads (49%) | called by muse, varscan2
- HTR1A | c.546G>A p.S182= | Silent (SNP) | VAF 352/352 reads (100%) | called by muse, varscan2
- HTR3A | c.846G>A p.L282= | Silent (SNP) | VAF 208/461 reads (45%) | called by muse, mutect2, varscan2
- HTT | c.7356C>A p.R2452= | Silent (SNP) | VAF 173/173 reads (100%) | called by muse, mutect2, varscan2
- IGLV3-27 | c.33C>T p.L11= | Silent (SNP) | VAF 265/291 reads (91%) | called by muse, mutect2, varscan2
- IGLV6-57 | c.102G>A p.G34= | Silent (SNP) | VAF 251/265 reads (95%) | catalogued as rs539326442; called by muse, mutect2, varscan2
- INPP4A | c.2371C>T p.L791= (on ENST00000074304 / NM_001134224.1; = p.L752= on NM_001566.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 278/605 reads (46%) | called by muse, mutect2, varscan2
- INSRR | c.1644G>A p.V548= | Silent (SNP) | VAF 153/491 reads (31%) | called by muse, mutect2, varscan2
- ITIH4 | c.1566G>A p.T522= | Silent (SNP) | VAF 124/331 reads (37%) | called by muse, mutect2, varscan2
- KMT2B | c.6837G>A p.K2279= | Silent (SNP) | VAF 305/527 reads (58%) | catalogued as rs1387911005; called by muse, mutect2, varscan2
- KRT77 | c.645G>A p.L215= | Silent (SNP) | VAF 171/512 reads (33%) | catalogued as rs1177292474; called by muse, mutect2
- LEMD3 | c.1053C>A p.S351= | Silent (SNP) | VAF 192/512 reads (38%) | catalogued as COSV100384106; called by mutect2, varscan2
- LRRC30 | c.33G>A p.K11= | Silent (SNP) | VAF 332/332 reads (100%) | catalogued as rs1424813774, COSV101274428; called by muse, mutect2, varscan2
- MACC1 | c.618G>A p.Q206= | Silent (SNP) | VAF 228/565 reads (40%) | called by muse, mutect2, varscan2
- MAP3K20 | c.777C>T p.I259= | Silent (SNP) | VAF 204/445 reads (46%) | called by muse, mutect2, varscan2
- MCM7 | c.2148C>T p.I716= | Silent (SNP) | VAF 204/378 reads (54%) | called by muse, varscan2
- MED13L | c.2739C>T p.F913= | Silent (SNP) | VAF 275/478 reads (58%) | catalogued as COSV56124846; called by muse, mutect2, varscan2
- MMP19 | c.1008C>T p.N336= | Silent (SNP) | VAF 318/557 reads (57%) | called by muse, mutect2, varscan2
- MMP26 | c.609C>T p.F203= | Silent (SNP) | VAF 140/349 reads (40%) | called by muse, mutect2, varscan2
- MROH2B | c.1317G>A p.L439= | Silent (SNP) | VAF 198/432 reads (46%) | called by muse, varscan2
- MROH2B | c.378T>G p.P126= | Silent (SNP) | VAF 193/435 reads (44%) | called by muse, mutect2, varscan2
- MTOR | c.6012C>T p.T2004= | Silent (SNP) | VAF 144/349 reads (41%) | called by muse, mutect2, varscan2
- MUC16 | c.27018G>A p.E9006= | Silent (SNP) | VAF 424/426 reads (100%) | called by muse, varscan2
- MYH8 | c.5083C>T p.L1695= | Silent (SNP) | VAF 450/450 reads (100%) | called by muse, mutect2, varscan2
- NALCN | c.1236G>A p.R412= | Silent (SNP) | VAF 172/172 reads (100%) | catalogued as COSV51923434; called by muse, mutect2, varscan2
- NAV2 | c.6474C>T p.P2158= (on ENST00000396087 / NM_001244963.2; = p.P2099= on NM_145117.5) | Silent (SNP) | VAF 172/340 reads (51%) | called by muse, varscan2
- NDRG3 | c.471C>T p.G157= (on ENST00000349004 / NM_032013.4; = p.G145= on NM_022477.4) | Silent (SNP) | VAF 208/311 reads (67%) | called by muse, mutect2, varscan2
- NEDD4L | c.2235C>T p.T745= (on ENST00000400345 / NM_001144967.3; = p.T725= on NM_015277.6) | Silent (SNP) | VAF 168/303 reads (55%) | called by muse, mutect2, varscan2
- NEDD4L | c.2236C>T p.L746= (on ENST00000400345 / NM_001144967.3; = p.L726= on NM_015277.6) | Silent (SNP) | VAF 167/301 reads (55%) | catalogued as COSV99895310; called by muse, mutect2, varscan2
- NEXMIF | c.1332C>T p.S444= | Silent (SNP) | VAF 395/395 reads (100%) | called by muse, varscan2
- NISCH | c.4134C>T p.S1378= | Silent (SNP) | VAF 192/496 reads (39%) | catalogued as rs1245861751; called by muse, varscan2
- NLRP7 | c.1173G>A p.T391= | Silent (SNP) | VAF 157/833 reads (19%) | catalogued as rs780110978; called by muse, mutect2, varscan2
- NPC1 | c.2077C>T p.L693= | Silent (SNP) | VAF 158/443 reads (36%) | called by muse, mutect2, varscan2
- NR4A3 | c.1563C>A p.S521= | Silent (SNP) | VAF 375/803 reads (47%) | called by muse, mutect2, varscan2
- OR2AJ1 | c.343C>T p.L115= | Silent (SNP) | VAF 144/364 reads (40%) | catalogued as rs1391282209; called by muse, varscan2
- OR2L2 | c.75C>T p.F25= | Silent (SNP) | VAF 144/232 reads (62%) | catalogued as rs201120288, COSV63551743; called by muse, varscan2
- OR4A15 | c.264G>A p.K88= | Silent (SNP) | VAF 201/366 reads (55%) | catalogued as rs373928337; called by muse, mutect2, varscan2
- OR4M1 | c.429C>T p.I143= | Silent (SNP) | VAF 305/578 reads (53%) | catalogued as rs763163557; called by muse, varscan2
- OR6K2 | c.465C>T p.P155= | Silent (SNP) | VAF 215/360 reads (60%) | catalogued as rs895546338, COSV62744092; called by muse, mutect2, varscan2
- OR6S1 | c.42C>T p.F14= | Silent (SNP) | VAF 196/452 reads (43%) | catalogued as rs747004005, COSV57837515; called by muse, mutect2
- OR6V1 | c.627C>T p.F209= | Silent (SNP) | VAF 398/887 reads (45%) | called by muse, mutect2, varscan2
- OR8J1 | c.936C>T p.S312= | Silent (SNP) | VAF 91/219 reads (42%) | catalogued as rs148720229; called by muse, varscan2
- ORC1 | c.927G>A p.K309= | Silent (SNP) | VAF 180/386 reads (47%) | called by muse, varscan2
- OVGP1 | c.1668C>T p.T556= | Silent (SNP) | VAF 259/513 reads (50%) | called by muse, mutect2, varscan2
- PALM2AKAP2 | c.1332C>T p.L444= (on ENST00000259318 / NM_001136562.3; = p.L675= on NM_007203.5) | Silent (SNP) | VAF 443/797 reads (56%) | catalogued as rs780836774; called by muse, mutect2, varscan2
- PARP3 | c.795C>T p.F265= | Silent (SNP) | VAF 171/476 reads (36%) | catalogued as rs760388246, COSV99232235; called by muse, varscan2
- PCF11 | c.2511A>G p.P837= | Silent (SNP) | VAF 184/356 reads (52%) | called by muse, varscan2
- PDZD7 | c.1302C>T p.S434= | Silent (SNP) | VAF 291/291 reads (100%) | catalogued as rs1358462226; called by muse, varscan2
- PI16 | c.762C>T p.T254= | Silent (SNP) | VAF 254/601 reads (42%) | called by muse, varscan2
- PIAS3 | c.1386C>T p.P462= | Silent (SNP) | VAF 344/513 reads (67%) | called by muse, mutect2, varscan2
- PIGQ | c.1497G>A p.L499= | Silent (SNP) | VAF 172/319 reads (54%) | called by muse, varscan2
- PIK3CD | c.286C>T p.L96= | Silent (SNP) | VAF 328/739 reads (44%) | catalogued as rs774791238; called by muse, mutect2, varscan2
- PLCZ1 | c.1726C>T p.L576= | Silent (SNP) | VAF 84/237 reads (35%) | catalogued as COSV56850406; called by muse, mutect2, varscan2
- PLSCR3 | c.825C>T p.F275= | Silent (SNP) | VAF 313/313 reads (100%) | called by muse, mutect2, varscan2
- PLXNA4 | c.1479A>G p.Q493= | Silent (SNP) | VAF 184/474 reads (39%) | called by muse, mutect2, varscan2
- POLG2 | c.678T>C p.N226= | Silent (SNP) | VAF 149/232 reads (64%) | called by muse, mutect2, varscan2
- PRUNE2 | c.7860G>A p.T2620= | Silent (SNP) | VAF 334/593 reads (56%) | catalogued as COSV65043504; called by muse, mutect2, varscan2
- PSD | c.705C>T p.I235= | Silent (SNP) | VAF 256/257 reads (100%) | catalogued as rs757010456, COSV50050441, COSV50068454; called by muse, varscan2
- PSD2 | c.1999T>C p.L667= | Silent (SNP) | VAF 43/388 reads (11%) | catalogued as rs753526958; called by muse, mutect2, varscan2
- PYHIN1 | c.630C>T p.F210= | Silent (SNP) | VAF 171/282 reads (61%) | catalogued as COSV63723729; called by muse, varscan2
- PZP | c.3888C>T p.F1296= | Silent (SNP) | VAF 278/418 reads (67%) | called by muse, varscan2
- PZP | c.339C>T p.F113= | Silent (SNP) | VAF 140/455 reads (31%) | catalogued as COSV54363494; called by muse, varscan2
- QTRT2 | c.429C>T p.C143= | Silent (SNP) | VAF 249/249 reads (100%) | called by muse, varscan2
- RASGRP2 | c.1389C>T p.A463= | Silent (SNP) | VAF 164/317 reads (52%) | called by muse, mutect2, varscan2
- RBP7 | c.189G>A p.V63= | Silent (SNP) | VAF 249/494 reads (50%) | catalogued as COSV53813653; called by muse, mutect2, varscan2
- RFWD3 | c.2019A>C p.R673= | Silent (SNP) | VAF 250/251 reads (100%) | called by muse, varscan2
- RIMS1 | c.384C>T p.C128= | Silent (SNP) | VAF 265/471 reads (56%) | catalogued as rs914659964, COSV53462888; called by muse, mutect2, varscan2
- RNF114 | c.225C>T p.V75= | Silent (SNP) | VAF 386/825 reads (47%) | called by muse, mutect2, varscan2
- SALL3 | c.2967G>A p.K989= | Silent (SNP) | VAF 550/1063 reads (52%) | catalogued as rs1295855931, COSV73306165; called by muse, mutect2, varscan2
- SCART1 | c.2235C>T p.F745= | Silent (SNP) | VAF 332/333 reads (100%) | called by muse, mutect2, varscan2
- SLC25A26 | c.673C>T p.L225= | Silent (SNP) | VAF 259/412 reads (63%) | called by muse, varscan2
- SLC26A11 | c.1137G>A p.A379= | Silent (SNP) | VAF 168/582 reads (29%) | catalogued as COSV63281490; called by muse, varscan2
- SLC7A10 | c.483C>T p.S161= | Silent (SNP) | VAF 41/372 reads (11%) | catalogued as COSV53505628; called by muse, mutect2, varscan2
- SLCO1B1 | c.945A>T p.G315= | Silent (SNP) | VAF 72/220 reads (33%) | called by muse, varscan2
- SLCO6A1 | c.795C>T p.I265= | Silent (SNP) | VAF 204/204 reads (100%) | called by muse, mutect2, varscan2
- SORBS1 | c.3387G>A p.R1129= | Silent (SNP) | VAF 387/387 reads (100%) | catalogued as COSV99528105; called by muse, mutect2, varscan2
- SOX12 | c.105C>T p.T35= | Silent (SNP) | VAF 438/659 reads (66%) | called by muse, varscan2
- SRRM2 | c.3234G>A p.Q1078= | Silent (SNP) | VAF 128/304 reads (42%) | called by muse, mutect2, varscan2
- SSC5D | c.4060C>T p.L1354= | Silent (SNP) | VAF 472/651 reads (73%) | called by muse, varscan2
- SUN1 | c.330G>A p.Q110= (on ENST00000405266 / NM_001367651.1; = p.Q60= on NM_025154.6 and 13 other RefSeq transcripts) | Silent (SNP) | VAF 307/534 reads (57%) | called by muse, mutect2, varscan2
- SZT2 | c.1164G>A p.K388= | Silent (SNP) | VAF 282/593 reads (48%) | called by muse, varscan2
- TBCD | c.2271C>T p.I757= | Silent (SNP) | VAF 252/404 reads (62%) | called by muse, varscan2
- TEKT5 | c.984G>A p.S328= | Silent (SNP) | VAF 157/380 reads (41%) | catalogued as rs1171439092, COSV51590763; called by muse, varscan2
- TENM1 | c.654G>A p.R218= | Silent (SNP) | VAF 379/380 reads (100%) | catalogued as rs751565049, COSV64445586; called by muse, mutect2, varscan2
- TERF2IP | c.951C>T p.I317= | Silent (SNP) | VAF 266/266 reads (100%) | called by muse, varscan2
- TET2 | c.3753G>A p.T1251= | Silent (SNP) | VAF 42/346 reads (12%) | catalogued as rs568289483; called by muse, varscan2
- TET3 | c.2892G>A p.R964= | Silent (SNP) | VAF 187/380 reads (49%) | called by muse, mutect2, varscan2
- TET3 | c.4314C>T p.Y1438= | Silent (SNP) | VAF 357/606 reads (59%) | catalogued as rs778156069; called by muse, mutect2, varscan2
- TFEC | c.423G>A p.K141= | Silent (SNP) | VAF 156/264 reads (59%) | catalogued as COSV55400033; called by mutect2, varscan2
- THNSL2 | c.738G>A p.L246= | Silent (SNP) | VAF 236/537 reads (44%) | called by muse, varscan2
- TIGD2 | c.879C>T p.F293= | Silent (SNP) | VAF 99/362 reads (27%) | catalogued as COSV57647802; called by muse, mutect2, varscan2
- TMEM132B | c.2472G>A p.Q824= | Silent (SNP) | VAF 248/567 reads (44%) | catalogued as COSV100170352; called by muse, mutect2, varscan2
- TMEM98 | c.147C>T p.L49= | Silent (SNP) | VAF 69/278 reads (25%) | called by muse, mutect2, varscan2
- TNFRSF11B | c.876C>T p.F292= | Silent (SNP) | VAF 178/472 reads (38%) | catalogued as rs752933989; called by muse, varscan2
- TP53I3 | c.372C>T p.A124= | Silent (SNP) | VAF 236/458 reads (52%) | catalogued as rs1262332567; called by muse, mutect2, varscan2
- TRAIP | c.1143G>A p.L381= | Silent (SNP) | VAF 157/434 reads (36%) | called by muse, mutect2, varscan2
- TRPV5 | c.1869C>T p.F623= | Silent (SNP) | VAF 296/723 reads (41%) | catalogued as rs758731434, COSV54682761; called by muse, mutect2, varscan2
- TSEN2 | c.1209C>T p.S403= | Silent (SNP) | VAF 279/465 reads (60%) | called by muse, mutect2, varscan2
- TTN | c.30009T>G p.P10003= (on ENST00000591111; = p.P9076= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 71/554 reads (13%) | called by muse, mutect2, varscan2
- TTN | c.28251G>A p.G9417= (on ENST00000591111; = p.G8490= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 203/486 reads (42%) | catalogued as COSV100611625; called by muse, varscan2
- TYK2 | c.1051C>T p.L351= | Silent (SNP) | VAF 356/365 reads (98%) | called by muse, varscan2
- TYK2 | c.1050C>T p.S350= | Silent (SNP) | VAF 362/362 reads (100%) | called by muse, varscan2
- VIT | c.1809G>A p.G603= (on ENST00000389975 / NM_001177969.1; = p.G618= on NM_053276.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 166/438 reads (38%) | called by muse, varscan2
- VPS39 | c.2215C>T p.L739= (on ENST00000348544 / NM_001301138.2; = p.L728= on NM_015289.5) | Silent (SNP) | VAF 99/184 reads (54%) | called by muse, mutect2, varscan2
- VWA8 | c.4422C>T p.L1474= | Silent (SNP) | VAF 56/132 reads (42%) | catalogued as COSV65002160; called by muse, varscan2
- WDR19 | c.60C>T p.A20= | Silent (SNP) | VAF 206/206 reads (100%) | catalogued as rs777240456; called by muse, mutect2, varscan2
- WDR49 | c.234C>T p.F78= (on ENST00000308378 / NM_001366158.1; = p.F419= on NM_001348951.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 207/208 reads (100%) | catalogued as rs367736932; called by muse, mutect2, varscan2
- XDH | c.108G>A p.L36= | Silent (SNP) | VAF 197/451 reads (44%) | called by muse, mutect2, varscan2
- XIRP2 | c.8274C>T p.S2758= (on ENST00000628543; = p.S2933= on NM_152381.6) | Silent (SNP) | VAF 176/406 reads (43%) | catalogued as rs778262913; called by muse, mutect2, varscan2
- ZCCHC14 | c.111C>T p.G37= (on ENST00000268616; = p.G174= on NM_015144.3) | Silent (SNP) | VAF 403/404 reads (100%) | catalogued as rs761735577; called by muse, varscan2
- ZCCHC2 | c.633G>A p.E211= | Silent (SNP) | VAF 548/892 reads (61%) | catalogued as rs1188413896; called by muse, varscan2
- ZIC1 | c.696C>T p.P232= | Silent (SNP) | VAF 512/512 reads (100%) | catalogued as COSV51556274, COSV99291929; called by muse, varscan2
- ZNF211 | c.432C>T p.F144= (on ENST00000347302 / NM_198855.4; = p.F157= on NM_006385.5) | Silent (SNP) | VAF 138/492 reads (28%) | catalogued as rs1373268445; called by muse, mutect2, varscan2
- ZNF488 | c.549G>A p.G183= | Silent (SNP) | VAF 361/361 reads (100%) | catalogued as rs781805678; called by muse, varscan2
- ZNF532 | c.1530C>T p.S510= | Silent (SNP) | VAF 379/573 reads (66%) | catalogued as rs1476977616; called by muse, varscan2
- ZNF813 | c.348C>T p.I116= | Silent (SNP) | VAF 47/322 reads (15%) | catalogued as COSV67177321; called by muse, mutect2, varscan2
- ZNF98 | c.1341A>C p.S447= | Silent (SNP) | VAF 272/277 reads (98%) | called by muse, varscan2
- ADNP | chr20:50889934 G>A | 3'Flank (SNP) | VAF 225/533 reads (42%) | catalogued as rs997849120; called by muse, mutect2, varscan2
- GABRD | c.554-19C>T | Intron (SNP) | VAF 418/782 reads (53%) | catalogued as rs1350010262; called by muse, varscan2
- GOLGA6L2 | c.*2A>T | 3'UTR (SNP) | VAF 320/432 reads (74%) | called by muse, mutect2, varscan2
- IP6K2 | c.202+122C>T | Intron (SNP) | VAF 316/518 reads (61%) | called by muse, varscan2
- KCNK4 | c.*35C>T | 3'UTR (SNP) | VAF 275/635 reads (43%) | catalogued as rs913774489; called by muse, mutect2, varscan2
- KCNQ1 | c.1394-7644C>T | Intron (SNP) | VAF 196/323 reads (61%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1514+6468A>C | Intron (SNP) | VAF 101/352 reads (29%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1514+33254T>G | Intron (SNP) | VAF 125/387 reads (32%) | called by muse, mutect2, varscan2
- MAGI1 | c.3635-1972G>A | Intron (SNP) | VAF 215/408 reads (53%) | catalogued as rs778591970, COSV100440603; called by muse, mutect2, varscan2
- MAP4 | c.2000-14277C>A | Intron (SNP) | VAF 92/266 reads (35%) | called by muse, varscan2
- MED24 | c.-6G>A | 5'UTR (SNP) | VAF 441/644 reads (68%) | called by muse, mutect2, varscan2
- MPP2 | c.32-2094G>A | Intron (SNP) | VAF 101/384 reads (26%) | called by muse, mutect2
- OGFOD3 | c.824-1866C>T | Intron (SNP) | VAF 206/294 reads (70%) | called by muse, varscan2
- PHLDB2 | c.1335+117del | Intron (DEL) | VAF 105/432 reads (24%) | called by mutect2, pindel, varscan2
- SEMA4D | chr9:89376981 C>T | 3'Flank (SNP) | VAF 325/838 reads (39%) | called by muse, varscan2
- SYTL2 | c.1459+92C>T | Intron (SNP) | VAF 154/369 reads (42%) | called by muse, mutect2, varscan2
- UNC13B | c.762-3008C>T | Intron (SNP) | VAF 207/209 reads (99%) | called by muse, mutect2, varscan2
- UNC13B | c.762-3007T>C | Intron (SNP) | VAF 209/212 reads (99%) | called by muse, mutect2, varscan2
- UTS2B | chr3:191262873 T>C | 3'Flank (SNP) | VAF 337/337 reads (100%) | called by muse, mutect2, varscan2
- ZDHHC3 | c.610+204T>C | Intron (SNP) | VAF 90/287 reads (31%) | called by muse, mutect2, varscan2
